Gene-level copy-number profile of tumor specimen TCGA-AJ-A2QM-01A from TCGA case TCGA-AJ-A2QM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.8 years (24,776 days).
Specimen TCGA-AJ-A2QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.094331c4-7236-4918-ba8e-6227aeea2926.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A2QM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66ed1384-e03b-4fd6-8032-5c319fb1b19c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 10,306; copy number 3: 11,027; copy number 4: 28,277; copy number 5: 4,585; copy number 6: 869; copy number 7: 3,170; copy number 8: 292; copy number 9: 216; copy number 10: 72; copy number 11: 592; copy number 12: 14; copy number 14: 33; copy number 15: 32; copy number 16: 176; copy number 20: 22; copy number 23: 67; copy number 26: 24; copy number 28: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A2QM-01A-11D-A18N-01): tumor purity 0.83, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:40,062,903–40,247,367, 4 genes: AC011266.1, LINC01477, RPL17P45, AC068688.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,277 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,600,404–173,336,965, 26 genes, copy number 10 (within-gene range 7–10): PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr5:161,751,448–163,437,326, 8 genes, copy number 9 (within-gene range 6–9): GLRXP3, GABRA1, LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6.
- chr5:178,941,191–181,342,213, 105 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr9:3,218,297–7,203,458, 86 genes, copy number 9–14 (broad region; genes not listed).
- chr10:16,823,966–17,229,985, 4 genes, copy number 9 (within-gene range 4–9): CUBN, AC067747.1, TRDMT1, VIM-AS1.
- chr10:59,176,643–59,650,345, 6 genes, copy number 11: PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1.
- chr10:74,744,386–78,029,515, 56 genes, copy number 10–28 (within-gene range 5–28): FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A.
- chr10:78,943,328–81,137,335, 67 genes, copy number 23 (broad region; genes not listed).
- chr17:5,116,032–5,175,034, 1 gene, copy number 11 (within-gene range 5–11): USP6.
- chr17:5,179,535–8,270,491, 177 genes, copy number 11–16 (within-gene range 7–16) (broad region; genes not listed).
- chr18:22,213,778–24,708,542, 52 genes, copy number 9–12 (within-gene range 6–12): AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915.
- chr18:25,818,234–27,190,698, 27 genes, copy number 9–10 (within-gene range 2–10): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2.
- chr18:70,003,031–71,944,577, 24 genes, copy number 10: RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2, AC090415.1, AC091691.3, AC091691.2, AC091691.1, LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2.
- chr18:76,209,422–80,033,949, 83 genes, copy number 15–20 (broad region; genes not listed).
- chr19:14,619,117–15,630,639, 50 genes, copy number 11: ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8.
- chr19:15,821,796–19,273,391, 200 genes, copy number 11 (broad region; genes not listed).
- chr21:36,430,360–46,665,124, 305 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
